Somatic mutation profile of tumor specimen TCGA-IG-A5B8-01A (aliquot TCGA-IG-A5B8-01A-11D-A28B-09) from TCGA case TCGA-IG-A5B8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 72.8 years (26,574 days).
Specimen TCGA-IG-A5B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e2affad-3d08-4fe7-b6f5-d8b4c8800710.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A5B8-10A (Blood Derived Normal), aliquot TCGA-IG-A5B8-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cab706a-91a9-4bb0-9d26-1c51a5c63179

The open-access MAF lists 291 somatic variants for this specimen: 194 protein-altering or splice-affecting, 94 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 94, Nonsense Mutation 16, Splice Site 5, Intron 2, Frame Shift Ins 2, Frame Shift Del 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4240T>G p.Y1414D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NF1 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as rs786203950, CM087437, CS983483, COSV62192041, COSV62210573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3638C>T p.S1213L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV53964655; called by muse, mutect2, varscan2
- ATF7IP | c.1670C>G p.S557C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1220452251; called by muse, mutect2, varscan2
- BRIP1 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555618733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C6orf89 | c.145C>G p.Q49E (on ENST00000373685; = p.Q56E on NM_152734.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV62100867; called by muse, mutect2, varscan2
- CABS1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441641724; called by muse, mutect2
- CFTR | c.1654C>G p.Q552E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM910072, CM962464; called by muse, mutect2
- CHST6 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV59999442; called by muse, mutect2, varscan2
- CLP1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs777290319, COSV57053898; called by muse, mutect2, varscan2
- CP | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs571448440, COSV52833013; called by muse, mutect2, varscan2
- CRACD | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV99949764; called by muse, mutect2, varscan2
- CREBRF | c.1773G>C p.Q591H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV51633139; called by muse, mutect2, varscan2
- CSMD3 | c.10149C>A p.H3383Q (on ENST00000297405 / NM_001363185.1; = p.H3214Q on NM_052900.3) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV52218533; called by muse, mutect2
- DNAH17 | c.3320G>C p.R1107T | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101102637; called by muse, mutect2, varscan2
- DNAI3 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV99641282; called by muse, mutect2
- DPP10 | c.2329T>G p.F777V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59710632, COSV59721562; called by muse, mutect2, varscan2
- EPX | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.083); catalogued as rs369339605; called by muse, mutect2, varscan2
- FARP1 | c.2251G>T p.D751Y | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100129833; called by muse, mutect2, varscan2
- FAT3 | c.8908C>T p.R2970* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs563792009, COSV53085725; called by muse, mutect2, varscan2
- GALNS | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as CD041913; called by muse, mutect2
- GALNT11 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147464952; called by muse, mutect2, varscan2
- GCC2 | c.2821G>A p.D941N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.82); catalogued as COSV59178482; called by muse, mutect2, varscan2
- GMEB1 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs201750134; called by muse, mutect2, varscan2
- GPR75 | c.35A>G p.N12S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); catalogued as rs775964311; called by muse, mutect2, varscan2
- GREB1 | c.4170G>C p.W1390C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.694); catalogued as COSV52183971; called by muse, mutect2, varscan2
- HTR1D | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58449113; called by muse, mutect2, varscan2
- INPP5E | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779363781, COSV65496093; called by muse, mutect2, varscan2
- IQGAP3 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100752237; called by muse, mutect2, varscan2
- ITPR3 | c.5644G>C p.E1882Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100967175; called by muse, mutect2, varscan2
- KDM5A | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as rs768653465, COSV66996680; called by muse, mutect2
- KIF20B | c.2486C>G p.S829* (on ENST00000371728 / NM_001284259.2; = p.S789* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs144738424; called by muse, mutect2, varscan2
- LRRC37A3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as rs1280308573; called by muse, mutect2
- MED7 | c.608A>T p.H203L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs148324701; called by muse, mutect2, varscan2
- MROH2B | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68187276; called by muse, mutect2, varscan2
- MUC16 | c.38996C>T p.S12999F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV67460482; called by muse, mutect2, varscan2
- MUL1 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402608714; called by muse, mutect2
- MYLK | c.3133G>C p.E1045Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV60607692; called by muse, mutect2, varscan2
- MYO18B | c.3540C>G p.I1180M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59128727; called by muse, mutect2, varscan2
- NANS | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs962328836; called by muse, mutect2, varscan2
- NCKAP5 | c.3280G>C p.D1094H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58462816, COSV58474131; called by muse, mutect2
- NELL1 | c.2183T>G p.L728R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs957167187, COSV54248990; called by muse, varscan2
- NIP7 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99650838; called by muse, mutect2, varscan2
- OR1S1 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as rs1308773903, COSV58707642; called by muse, mutect2, varscan2
- OR8H2 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs1429715751, COSV57944790, COSV57945198; called by muse, mutect2, varscan2
- P3H1 | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772830417, COSV52538500; called by muse, mutect2, varscan2
- PARD3 | c.2549C>G p.S850* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV60761019; called by muse, mutect2, varscan2
- PBDC1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100972862; called by muse, mutect2, varscan2
- PKHD1L1 | c.814G>C p.V272L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV101007106; called by muse, mutect2, varscan2
- PRMT1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750309006, COSV101212225, COSV67159705; called by muse, mutect2, varscan2
- RELN | c.7282C>G p.R2428G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV58991199; called by muse, mutect2, varscan2
- REV1 | c.3525G>T p.W1175C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307566723; called by muse, mutect2
- RHCE | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs201407774, CM058209, COSV53801296; called by muse, mutect2, varscan2
- RILPL2 | c.530G>T p.R177I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.294); catalogued as COSV54912143; called by muse, mutect2, varscan2
- RP1 | c.2541G>C p.L847F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV55120233; called by muse, mutect2, varscan2
- RYR2 | c.13508G>A p.R4503K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.973); catalogued as COSV63684097; called by muse, mutect2, varscan2
- RYR2 | c.13718G>A p.R4573H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs371157286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3E | c.2064G>T p.E688D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57113821; called by muse, mutect2, varscan2
- SHPRH | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.916); catalogued as rs577017273; called by muse, mutect2, varscan2
- SIGLEC1 | c.3508+1G>A p.X1170_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | catalogued as COSV52466387; called by muse, mutect2, varscan2
- SLC30A10 | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as rs375331656; called by muse, mutect2, varscan2
- SLC5A12 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs1298812101, COSV54824218; called by muse, mutect2, varscan2
- SNAP91 | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99534938, COSV99536322; called by muse, mutect2, varscan2
- SOX13 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.483); catalogued as rs764676220; called by muse, mutect2, varscan2
- SOX14 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs777197594, COSV60163212; called by muse, mutect2
- SPAG6 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV57617893, COSV57619580, COSV57620243; called by muse, mutect2
- TMX3 | c.51_53del p.V18del | In Frame Del (DEL) | VAF 15/27 reads (56%) | catalogued as rs769980242; called by pindel, varscan2
- TNPO1 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs113424229; called by muse, mutect2, varscan2
- TPM4 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as rs368923322; called by muse, mutect2, varscan2
- TSC1 | c.757C>A p.H253N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100051352; called by muse, mutect2, varscan2
- TTC21A | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1303460020; called by muse, mutect2
- VGLL4 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377034464; called by muse, mutect2, varscan2
- XRCC6 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV63753854; called by muse, mutect2, varscan2
- ZBTB48 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as rs549375724; called by muse, mutect2, varscan2
- ZFYVE1 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV59612759; called by muse, mutect2
- ZNF101 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.101); catalogued as rs758983961, COSV58908705; called by muse, mutect2, varscan2
- ZNF202 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as rs575384396, COSV60246821; called by muse, mutect2, varscan2
- ZNF672 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as rs1448175059; called by muse, mutect2, varscan2
- ZSCAN5B | c.476G>C p.R159T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.118); catalogued as COSV62838517; called by muse, mutect2, varscan2
- ABCF2 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- AC008397.2 | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ACD | c.718G>T p.E240* (on ENST00000620338; = p.E151* on NM_022914.3) | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- AEBP1 | c.787del p.R263Gfs*29 | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- ALDH18A1 | c.1805G>T p.R602I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ALKBH7 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANGPTL6 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- AP002748.5 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ARFGEF3 | c.5092G>C p.D1698H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2
- ARHGEF35 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2, varscan2
- C14orf180 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf105 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2
- C7 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1E | c.5420C>G p.S1807C | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CALM3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- CAND2 | c.3465G>T p.R1155S (on ENST00000456430 / NM_001162499.2; = p.R1038S on NM_012298.3) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CAPZB | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- CARMIL1 | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CATSPER3 | c.493-1G>A p.X165_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- CCDC146 | c.987-1G>A p.X329_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- CD151 | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CERS5 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CHD6 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CHRND | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHSY3 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.565); called by muse, mutect2
- CNGB1 | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CREB3L1 | c.531G>C p.M177I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP51A1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DNAH10 | c.6475C>T p.Q2159* (on ENST00000409039; = p.Q2098* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- DOCK2 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DSEL | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DYNC2H1 | c.10789G>A p.V3597I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYRK1B | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EMP1 | c.2dup p.M1? | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- EPHX1 | c.651C>A p.F217L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, varscan2
- EPHX1 | c.1294T>A p.F432I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXOC3L1 | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- FAM135A | c.3377G>A p.R1126K (on ENST00000370479 / NM_001351599.1; = p.R913K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83G | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- FGD4 | c.744G>C p.E248D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- FNDC1 | c.5285-8_5300del p.X1762_splice | Splice Site (DEL) | VAF 22/118 reads (19%) | called by mutect2, pindel
- FTH1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GTF3C1 | c.5710G>A p.G1904R | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- H2BC18 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); called by muse, mutect2
- H3C6 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HAX1 | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPACAM2 | c.691G>A p.D231N (on ENST00000394468 / NM_001039372.4; = p.D219N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- HLA-DQA2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ICE1 | c.4879G>C p.E1627Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ICE1 | c.5854G>C p.E1952Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFI16 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IL6ST | c.1401C>G p.I467M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- INO80C | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IQSEC3 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ISG20 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- JAKMIP3 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LAMA2 | c.5727-1G>C p.X1909_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- LONP2 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2
- LRP5 | c.604A>T p.I202F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MANEA | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP1A | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by mutect2, varscan2
- MAP3K14 | c.2327A>T p.E776V | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARF1 | c.2597C>G p.S866* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- MCM3 | c.2091G>C p.Q697H (on ENST00000229854 / NM_001366374.2; = p.Q687H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MMP16 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MPP5 | c.198G>C p.M66I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- MT1H | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- NIPAL3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NLK | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NLRX1 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- NOXRED1 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OPTN | c.1501A>G p.K501E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- OR11A1 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- OR2T11 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- OS9 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PARP8 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 115/360 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- PAX1 | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PER1 | c.3456G>A p.M1152I | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGBD2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGC | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PJA2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PKHD1L1 | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLAC9 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- PLEC | c.7486G>A p.E2496K (on ENST00000322810 / NM_201380.4; = p.E2386K on NM_000445.5) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKD1 | c.2015C>G p.S672* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- PRLR | c.746G>C p.C249S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRRC1 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- R3HDML | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAG1 | c.1952C>G p.S651C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM14 | c.208A>T p.M70L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHBG | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RPRD1A | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- SATB2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SEMA4C | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.42); called by muse, mutect2
- SHANK2 | c.3973G>C p.D1325H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SLC50A1 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- SLC9C1 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2
- SMAD9 | c.1363C>T p.Q455* (on ENST00000379826 / NM_001127217.3; = p.Q418* on NM_005905.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- SNRPD2 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SYNE2 | c.15546G>C p.L5182F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAF1B | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- TBCD | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TINF2 | c.1214_1215dup p.G406Kfs*17 | Frame Shift Ins (INS) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- TNXB | c.8898G>C p.E2966D (on ENST00000647633; = p.E2719D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- TRRAP | c.10332G>C p.W3444C (on ENST00000359863 / NM_001244580.1; = p.W3415C on NM_003496.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRRAP | c.10429G>A p.E3477K (on ENST00000359863 / NM_001244580.1; = p.E3448K on NM_003496.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- UBE2F | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- VN1R1 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- VPS13B | c.7672G>C p.E2558Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VPS13C | c.7993C>T p.H2665Y (on ENST00000644861 / NM_020821.3; = p.H2622Y on NM_017684.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR7 | c.1502C>G p.S501C | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZNF292 | c.7871A>G p.H2624R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, varscan2
- ZNF540 | c.1868C>G p.T623S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF804A | c.565A>C p.S189R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ACACB | c.3135C>T p.I1045= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- ACSF3 | c.21C>T p.L7= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1372111364; called by muse, mutect2
- ACTN4 | c.1260G>A p.Q420= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs1043958961, COSV53143771; called by muse, mutect2, varscan2
- AMBRA1 | c.1725G>A p.L575= (on ENST00000458649 / NM_001367468.1; = p.L485= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- C5AR2 | c.42C>T p.S14= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs138403580, COSV57257570; called by muse, mutect2, varscan2
- CA14 | c.892T>C p.L298= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1560028105; called by muse, mutect2, varscan2
- CCDC27 | c.606G>A p.K202= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1324498847, COSV53901607; called by muse, mutect2, varscan2
- CEACAM6 | c.609C>G p.L203= | Silent (SNP) | VAF 64/237 reads (27%) | called by muse, mutect2, varscan2
- CENPC | c.1464T>G p.T488= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- CEP128 | c.2100C>A p.L700= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV99825896; called by muse, mutect2, varscan2
- CFAP61 | c.3039C>G p.L1013= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV55651418; called by muse, mutect2, varscan2
- CHRM4 | c.753G>A p.K251= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs201352810; called by muse, mutect2, varscan2
- CYP39A1 | c.396C>G p.L132= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- DNAH1 | c.7590C>T p.L2530= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- DOCK11 | c.3519A>G p.L1173= | Silent (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- DSPP | c.669G>A p.G223= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- EGFLAM | c.2325C>T p.F775= | Silent (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- EHMT2 | c.3624C>G p.V1208= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs1181432069; called by muse, mutect2, varscan2
- ELF5 | c.267C>T p.F89= (on ENST00000312319 / NM_198381.2; = p.F79= on NM_001422.4) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1178288156; called by muse, mutect2, varscan2
- FAM193B | c.1761C>G p.L587= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- FMO2 | c.408G>A p.Q136= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV52946464, COSV52949339; called by muse, mutect2, varscan2
- GATA4 | c.1212G>A p.K404= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs780419565; called by muse, mutect2, varscan2
- GCH1 | c.721C>A p.R241= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as CM011360; called by muse, mutect2
- GCM2 | c.528G>A p.K176= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- GHR | c.1113G>A p.E371= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV50123930; called by muse, mutect2
- GLI4 | c.501C>G p.V167= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV60683010; called by muse, mutect2, varscan2
- GUCY2D | c.1554C>T p.G518= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- HAL | c.144G>A p.V48= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs758513871; called by muse, mutect2, varscan2
- HMCN1 | c.8673G>A p.L2891= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- HSD11B2 | c.954C>T p.L318= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- ICAM1 | c.1074G>A p.L358= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- IER2 | c.138C>G p.L46= | Silent (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- IMPDH1 | c.315G>A p.R105= (on ENST00000470772 / NM_001142573.2; = p.R190= on NM_000883.4) | Silent (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- KCNV1 | c.150C>T p.F50= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV52086006, COSV52088219; called by muse, mutect2
- KCTD16 | c.1059G>C p.L353= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV72577123; called by muse, mutect2
- KLHL26 | c.201G>C p.L67= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- LAMB3 | c.1527G>A p.L509= | Silent (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- LAX1 | c.1164G>A p.Q388= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- LMF1 | c.111C>T p.P37= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, varscan2
- MSLN | c.72G>T p.L24= | Silent (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
- MUC16 | c.2514C>T p.L838= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV101197475, COSV67464116; called by muse, mutect2, varscan2
- MYLK3 | c.1800G>T p.R600= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- NAA11 | c.204G>A p.P68= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs762585511, COSV54513872, COSV54513940; called by muse, mutect2, varscan2
- NAB2 | c.966C>T p.I322= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- NLRP1 | c.3369G>A p.V1123= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1317801191; called by muse, mutect2
- NLRP5 | c.174C>T p.L58= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- NPHP4 | c.2358C>T p.V786= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as rs371647995; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTN3 | c.957C>T p.R319= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- OR13C9 | c.903G>A p.K301= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as rs1239789737; called by muse, mutect2, varscan2
- OR56A1 | c.297C>A p.A99= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- OSR2 | c.855C>T p.S285= (on ENST00000297565 / NM_001142462.3; = p.A258V on NM_053001.3) | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52557224; called by muse, mutect2, varscan2
- PCDHAC1 | c.915C>G p.L305= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- PCDHB1 | c.867C>G p.L289= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- PDIA4 | c.1584C>T p.V528= (on ENST00000286091 / NM_001371244.1; = p.V527= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- PHLPP1 | c.4863G>T p.R1621= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- PLEC | c.9276C>A p.I3092= (on ENST00000322810 / NM_201380.4; = p.I2982= on NM_000445.5) | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- PODNL1 | c.660C>T p.L220= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54309655; called by muse, mutect2, varscan2
- POU4F2 | c.1134C>T p.I378= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs572053159, COSV55583817, COSV99850480; called by muse, mutect2, varscan2
- PPFIA4 | c.531G>A p.E177= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1261337751; called by muse, mutect2, varscan2
- PPP4R4 | c.1956G>C p.V652= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58557538; called by muse, mutect2, varscan2
- PTPRN2 | c.2994G>A p.A998= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs765163209; called by muse, mutect2, varscan2
- RASGRF1 | c.1998G>A p.L666= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- REV1 | c.3753A>G p.T1251= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- RNFT2 | c.687C>G p.L229= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- RPAP1 | c.2358G>A p.E786= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1399855877; called by muse, mutect2, varscan2
- RUNDC3B | c.111C>T p.I37= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- RXRG | c.1086G>A p.Q362= | Silent (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- SEC24D | c.2910C>G p.L970= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- SECISBP2L | c.2682G>A p.E894= (on ENST00000559471 / NM_001193489.2; = p.E849= on NM_014701.4) | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- SLC22A4 | c.756C>T p.F252= | Silent (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- SLC26A4 | c.1317G>A p.G439= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as CS1314021; called by muse, mutect2, varscan2
- SLC39A4 | c.1943G>A p.*648= (on ENST00000301305 / NM_001374839.1; = p.*623= on NM_017767.3) | Silent (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- SLC4A2 | c.2091G>A p.L697= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- SOS2 | c.759G>A p.L253= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- STC1 | c.579C>G p.L193= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.1686G>A p.P562= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs765453681; called by muse, mutect2
- TACR1 | c.198G>A p.V66= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV59485361; called by muse, mutect2, varscan2
- TECR | c.594C>T p.L198= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV53108610; called by muse, varscan2
- TMCO1 | c.270G>A p.L90= (on ENST00000612311 / NM_001256164.1; = p.L39= on NM_019026.6) | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- TMEM214 | c.1464G>A p.L488= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- TRIM10 | c.231C>T p.N77= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs762205559, COSV64989901; called by muse, mutect2, varscan2
- TUBA3E | c.1191C>G p.L397= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs759535569; called by muse, mutect2, varscan2
- UBE2D2 | c.54A>T p.P18= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54077679; called by muse, mutect2, varscan2
- UBR4 | c.1977C>A p.T659= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- UNKL | c.174C>G p.L58= | Silent (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- USH2A | c.12810G>A p.V4270= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1409825126; called by muse, mutect2, varscan2
- UTP14C | c.1125C>T p.F375= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1157082884; called by muse, mutect2, varscan2
- VENTX | c.570C>T p.S190= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs767616096, COSV58084048; called by muse, mutect2, varscan2
- XKR3 | c.129C>A p.L43= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV58885344; called by muse, mutect2, varscan2
- YME1L1 | c.471C>G p.V157= (on ENST00000326799 / NM_139312.3; = p.V100= on NM_014263.4) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV58759292; called by muse, mutect2, varscan2
- ZBTB14 | c.942C>T p.F314= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV63697371; called by muse, mutect2, varscan2
- ZBTB38 | c.864C>G p.S288= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- ZEB1 | c.1707T>C p.P569= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- ZNF292 | c.2781T>A p.T927= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- BMP1 | c.2107+1928C>G | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- DMPK | c.161-463G>C | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as rs1190388449; called by muse, mutect2, varscan2
- DNAJC24 | c.-1G>C | 5'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
